Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A1OF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A1OF-01A (Primary Tumor).

[page 1 of 4]
surg path rpt

ICD-0-3

Adenocarcinoma, Serous, NOS
Site: endometrium C54.1 8441/3
3/4/11 lw

Ord #=
Ord Clin=
Resulted by= SYS, SYSTEM
Item Comment:
Item Custom Questions:
How Many Part Types: 6
SURGICAL PATHOLOGY
Modifiers:
SURGICAL PATHOLOGY:
CoPath Specimen

ASAP
RESULTED

Sched D/T=
Collect D/T=
Result D/T=

(1 of 1)

Source:

A: Uterus, Cervix, bilateral tubes \T\ ovaries, (Frozen section)
B: Omentum, (Permanent)
C: Right Pelvic lymph node
D: Left Pelvic lymph node
E: Left Para-aortic lymph node
F: Right Para-aortic lymph node

Final Diagnosis

A. Uterus, cervix, bilateral tubes and ovaries (F/S, TAH, BSO):
Histologic Type: Endometrioid adenocarcinoma, FIGO Grade III
(70%); Serous adenocarcinoma
(30%).
Histologic Grade (for Endometrioid carcinoma): FIGO grade 3
For serous carcinomas: G3: Poorly differentiated
Tumor Site: fundus/ endometrium
Tumor Size: 2.5 cm
Myometrial Invasion: Present
Depth of invasion: 2 mm
Myometrial thickness: 15 mm
Cervix, endocervix, lower uterine segment: Not involved
Bilateral ovaries, fallopian tubes, bilateral parametrium: Not
involved
Margins: Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: more
than 10 mm (Uterine serosa)
Lymph-Vascular Invasion: Not identified

Pathologic Staging

pT1a [IA]: Tumor limited to endometrium or invades less
than one-half of the myometrium
pN0: No regional lymph node metastasis

MX

Additional Pathologic Findings: Bilateral chronic salpingitis.

B. Omentum, omentectomy:

Printed By:
Printed:

Confidential Patient Information
NOT A CHART COPY

Page 1

[page 2 of 4]
SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

Adm: [REDACTED]

- Benign fibroadipose tissue.
- 13 benign diminutive lymph nodes (0/13).
- C. Right pelvic lymph nodes, dissection:
- 3 benign lymph nodes (0/3).
- D. Left pelvic lymph nodes, dissection:
- 1 benign lymph node (0/1).
- E. Left paraaortic lymph node, dissection:
- No lymph node.
- F. Right paraaortic lymph nodes, dissection:
- 3 benign lymph nodes (0/3).

***Electronically Signed Out

Comment(s)

The previous EMB report is noted.

Pre Operative Diagnosis
Highly grade endometrial CAOperation Performed
EUA, TAH BSO, Bil. pelvic intracolic omental bxIntraoperative Diagnosis
FS#1: Endometrium: FIGO Grade III endometrioid carcinoma with focal high nuclear grade, probable serous component. Superficial myometrial invasion.

FS#2: Cervix, endocervix, and lower uterine segment: No malignancy.

Signed by

Gross Description
The specimen is submitted in 6 parts, labeled as in formalin fixative.

Specimen A is labeled as "Uterus, cervix, bilateral tubes \T\ ovaries (F/S)", consists of uterus, cervix, and bilateral

Printed By:
Printed:Confidential Patient Information
NOT A CHART COPY

Page 2

[page 3 of 4]
SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

Adm: [REDACTED]

adnexa, weighing 84 grams in total and measuring 4.5cm in width, 8.0cm in length, 3.5cm in anterior posteriorly for the uterus, 2.5 x 1.0 x 0.7cm for the right ovary, 4.0 x 1.0 x 0.7cm for the left ovary. The cervix is unremarkable and measuring 1.5cm in width, 1.5cm in anteroposteriorly. The parametrial margins are inked black. When it is opened it shows uterus fundus with polypoid tumor, measuring 2.5 x 2.0 x 1.0 cm. The serial sectioning shows superficial myometrial invasion in the posterior aspect.

The cut surface of the bilateral ovary shows fibrotic atrophic appearance without tumor. The mucosa surface of cervix and endocervix is unremarkable. In the lower interior segments there are minute polypoid lesion measuring 0.2cm. The representative section of the tumor of endometrium is submitted into frozen section #1, resubmitted into cassette A1. The representative sections of the cervix, endocervix and lower endo segment with polypoid lesion is submitted into frozen section #2, resubmitted into cassette A2. Bilateral fallopian tubes are unremarkable except for serosal hematoma, measuring 2.0cm in greatest dimension.

Cassette summary:

- A3- anterior cervix,
- A4- posterior cervix,
- A5- lower uterine segment
- A6 ,A7- right adnexa
- A8- left adnexa
- A9- right parametrial tissue,
- A10-left parametrial tissue
- A11-A13- additional tumor with myometrium
- A14- unremarkable endomyometrium.

Specimen B is labeled as "Omentum" (permanent)", consists of one piece of fibroadipose tissue, weighing 90 gram and measuring 31 cm x 2.0 x 1.5 cm. The surface of the fatty tissue shows unremarkable yellowish fat without definitive tumor nodules or lymph nodes. Representative sections are summarized into B1-B4.

Specimen C is labeled as "Rt pelvic lymph node", consists of a few fragments of fibroadipose tissue, measuring in aggregate 4.5 x 3.0 x 1.0 cm. A few lymph nodes are identified, each is bisected and submitted in to cassettes C1-C3. The fatty tissue with nodularity is submitted into cassette C4.

Printed By:
Printed:

Confidential Patient Information
NOT A CHART COPY

Page 3

[page 4 of 4]
SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] Adm: [REDACTED]

Specimen D is labeled "Left pelvic lymph node, consists of several fragments of fibroadipose tissue and pinkish nodular area, measuring in average 3.5 x 2.0 x 1.0cm. The nodular areas are bisected and submitted entirely in D1 and D2.

Specimen E is labeled as "Left paraaortic lymph node", consists of one piece of hemorrhagic nodular tissue, measuring 1.0 x 0.5 x 0.7cm. The specimen is bisected and submitted into cassette E1.

Specimen F is labeled as "Right paraaortic lymph node", consists of whitish oval nodule tissue, measuring 2.6 x 1.5 x 0.7 cm. The specimen is bisected and submitted into cassettes F1 and F2 entirely.

Microscopic Description
Was performed.

* System: ***** For: *
* End: *

Printed By:
Printed:

Confidential Patient Information
NOT A CHART COPY

Page 4

dPAA Discrepancy		/

Source: NCI Genomic Data Commons file 0d3326bc-541c-4662-bd72-395ab625bf15 (TCGA-A5-A1OF.C0A753A3-5202-4DD2-948E-2921AFBCB3BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).